Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-A8B7, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-A8B7-TTP2-C (Primary Tumor).

Material description

- A) Right lung, lower lobe
- B) Lung, paratracheal lymph nodes
- C) Lung, tracheobronchial lymph nodes
- D) Lung, subcarinal lymph nodes
- E) Lung, lobar lymph nodes of the middle lobe
- F) Lung, lymph nodes of upper lobe
- G) Lung, lymph nodes of pulmonary ligament
- H) Lung, interlobar lymph nodes

Macrodescription

- A) Pulmonary lobe with area of pleural retraction corresponding to, when you cut, a nodular, greyish and necrotic injury, badly defined margins, about 4 cm of diameter.
- B) Multiple and blackish lymph nodes, largest of 0.5 cm
- C) Multiple and blackish lymph nodes, largest of 0.5 cm
- D) 2 lymph nodes, maximum diameter of 2 cm each
- E) A lymph node of 1 cm
- F) A lymph node of 1 cm
- G) A lymph node of 0.5 cm
- H) 2 lymph nodes of 2 cm and 1 cm.

Microdescription

- A) Large cell carcinoma of lung, clear cell type, widely necrotic, infiltrating the visceral pleura and the lobar bronchus whose margin of surgical resection is free.
- B-C) We don't observe metastases in 5 lymph nodes
- D) Metastases in a lymph node of a package of incorporated lymph nodes (about 10 lymph nodes)
- E) We don't observe metastases in 1 lymph node
- F) We don't observe metastases in 2 lymph nodes
- G) We don't observe metastases in 1 lymph node
- H) We don't observe metastases in 3 lymph nodes

Staging pTNM: pT2, N+, Mx

ICD-0-3

carcinoma, large cell 8012/3 (code to highest)
carcinoma, clear cell 8310/3
Site: (R) lung, lower lobe C34.3

ICD-10

C34.31

hw
2/10/16

CDDP-YP-A887-01-PR

Source: NCI Genomic Data Commons file 68aea5fa-8649-44ff-9d40-2dc0ed075991 (CDDP-A8B7-TTP2.EFDF6C73-8873-4512-844E-6DFFC23FC6BC.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).